Somatic mutation profile of tumor specimen TCGA-DA-A1I1-06A (aliquot TCGA-DA-A1I1-06A-12D-A196-08) from TCGA case TCGA-DA-A1I1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.8 years (25,133 days).
Specimen TCGA-DA-A1I1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b329dc36-e310-4a06-be0e-29ebb4579339.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1I1-10A (Blood Derived Normal), aliquot TCGA-DA-A1I1-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbd01fa4-425d-4e6e-accf-4856bce78fcf

The open-access MAF lists 446 somatic variants for this specimen: 303 protein-altering or splice-affecting, 131 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 281, Silent 131, Nonsense Mutation 15, Intron 4, RNA 3, Splice Site 3, Frame Shift Del 3, 5'UTR 2, 3'UTR 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ5 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59663556; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 48/114 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- SLC12A3 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs747249619, CM981832, COSV52636699; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA12 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs1178102703, COSV55953601, COSV99791271; called by mutect2, varscan2
- ABCA13 | c.4795C>T p.H1599Y | Missense Mutation (SNP) | VAF 123/274 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV70035354; called by mutect2, varscan2
- ABCA13 | c.13424G>A p.S4475N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as COSV68948812; called by muse, mutect2, varscan2
- ABCC5 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55593247; called by muse, mutect2, varscan2
- ACE | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs921762904, COSV52010030; called by muse, mutect2, varscan2
- ADAM19 | c.2119G>T p.V707L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs1042932912, COSV57434308, COSV57441164; called by mutect2, varscan2
- ADAM7 | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51543032; called by mutect2, varscan2
- ADAMTS4 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV63490658; called by muse, mutect2, varscan2
- ADD3 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV53324437; called by muse, mutect2, varscan2
- ADH1B | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 89/287 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV59297502; called by muse, mutect2, varscan2
- AGL | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54055451; called by muse, mutect2, varscan2
- AGMO | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV61117492; called by muse, varscan2
- APOB | c.9445G>A p.D3149N | Missense Mutation (SNP) | VAF 233/570 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as rs759354804, COSV51934474, COSV51935706; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ASXL3 | c.2392A>T p.T798S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.009); catalogued as COSV99326837; called by muse, mutect2, varscan2
- ASXL3 | c.2393C>T p.T798I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52475413, COSV99326842; called by muse, mutect2, varscan2
- ATF7IP | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV53773909; called by muse, mutect2, varscan2
- ATG9A | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54698441; called by muse, mutect2, varscan2
- ATP1A3 | c.1802C>T p.A601V (on ENST00000545399 / NM_001256214.2; = p.A588V on NM_152296.5) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs1555862095, COSV57489290; called by muse, mutect2, varscan2
- BAZ2B | c.5783C>T p.S1928L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58596461, COSV58605145; called by mutect2, varscan2
- BSN | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV56522551; called by muse, mutect2, varscan2
- BTBD7 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV58288499; called by muse, mutect2, varscan2
- BTN3A1 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.985); catalogued as COSV50024743; called by muse, mutect2, varscan2
- BTNL8 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV51460061; called by muse, mutect2, varscan2
- C1orf141 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV63992985; called by muse, mutect2, varscan2
- C1orf226 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1252419120, COSV63396085; called by mutect2, varscan2
- C20orf96 | c.239C>T p.P80L (on ENST00000360321 / NM_153269.3; = p.P79L on NM_080571.1) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV64404010; called by muse, mutect2, varscan2
- CARD11 | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.545); catalogued as rs764490474, COSV67796927; called by mutect2, varscan2
- CARD6 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1490074721, COSV54567448; called by mutect2, varscan2
- CASP3 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1457645538, COSV57724877; called by muse, varscan2
- CCDC102B | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as rs199750681; called by mutect2, varscan2
- CCDC73 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); catalogued as COSV100067544, COSV58799301, COSV58801359; called by muse, mutect2, varscan2
- CCSER1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1215145266, COSV61432014; called by muse, mutect2, varscan2
- CDH8 | c.569C>G p.T190S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV54881850; called by muse, mutect2, varscan2
- CFAP100 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1490765014, COSV61503722; called by muse, mutect2, varscan2
- CHD6 | c.3404G>A p.R1135H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58556670, COSV58559502; called by mutect2, varscan2
- CHIT1 | c.926G>A p.W309* | Nonsense Mutation (SNP) | VAF 40/94 reads (43%) | catalogued as COSV55148109; called by muse, mutect2, varscan2
- CHL1 | c.2629G>A p.G877R (on ENST00000397491 / NM_001253387.1; = p.G893R on NM_006614.4) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV56598072; called by muse, mutect2, varscan2
- CHODL | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV54732677; called by muse, mutect2, varscan2
- CLDN4 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs782109306, COSV52896507; called by mutect2, varscan2
- CMYA5 | c.5327G>A p.G1776E | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV71404461; called by muse, mutect2, varscan2
- CNGA3 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV55624555; called by muse, mutect2, varscan2
- CNTN5 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs942238616, COSV54281179; called by muse, mutect2, varscan2
- COL28A1 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.045); catalogued as rs747071568, COSV68083288; called by muse, mutect2, varscan2
- COL3A1 | c.4141C>T p.Q1381* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV58592922; called by mutect2, varscan2
- COL4A1 | c.3364C>T p.L1122F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs749746856, COSV65428401; called by muse, varscan2
- CPSF1 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1554864044, COSV100450757; called by mutect2, varscan2
- CPSF1 | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV100450762; called by muse, mutect2, varscan2
- CSMD1 | c.2399C>T p.T800I (on ENST00000520002; = p.T799I on NM_033225.6) | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.806); catalogued as COSV59349417; called by muse, mutect2, varscan2
- CTNNA3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV65602250; called by muse, mutect2, varscan2
- CUX1 | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as COSV52906237; called by muse, mutect2, varscan2
- CYFIP2 | c.210T>G p.N70K | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV59045823; called by muse, mutect2, varscan2
- CYLC2 | c.699A>T p.E233D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV66338681; called by muse, mutect2, varscan2
- CYP2A13 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV57838922; called by muse, mutect2, varscan2
- CYP2C9 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV53250549; called by muse, mutect2, varscan2
- CYP4F3 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967842174, COSV55409414; called by muse, mutect2, varscan2
- CYTIP | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs866095217, COSV51634551, COSV51634992; called by muse, mutect2, varscan2
- CYYR1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs948658869, COSV54832193; called by mutect2, varscan2
- DAB1 | c.1577C>T p.S526F (on ENST00000371231; = p.S493F on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV64692848; called by muse, mutect2, varscan2
- DDX27 | c.1760A>G p.K587R | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65609141; called by muse, mutect2, varscan2
- DEFB118 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868083733, COSV53620529; called by muse, mutect2, varscan2
- DHX57 | c.3247C>T p.P1083S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.928); catalogued as COSV54887840; called by muse, varscan2
- DNAH8 | c.3967C>T p.P1323S | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59463231; called by muse, mutect2, varscan2
- DNAH8 | c.8858C>T p.S2953F | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59434673; called by muse, mutect2, varscan2
- DNAJA3 | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52162997; called by muse, mutect2, varscan2
- DNAJC18 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs143797552; called by mutect2, varscan2
- DSC2 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV51866954; called by muse, mutect2, varscan2
- DSP | c.7790C>T p.S2597F | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV65793967; called by muse, mutect2, varscan2
- DTNA | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52016275; called by muse, mutect2, varscan2
- DYNC2I1 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as rs1437014056, COSV101337702, COSV68105869; called by muse, mutect2, varscan2
- E2F2 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs1476814390, COSV62276582; called by muse, mutect2, varscan2
- EFCAB6 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV53060762; called by muse, mutect2, varscan2
- EFEMP1 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as rs752116761, COSV62616945; called by muse, mutect2, varscan2
- EFL1 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs752165394, COSV51604250, COSV99186344; called by mutect2, varscan2
- EIF2AK1 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV52241086; called by muse, mutect2, varscan2
- EMILIN2 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54422643; called by muse, varscan2
- EPHB4 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62269690; called by muse, mutect2, varscan2
- EPHB6 | c.2713C>G p.R905G | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.202); catalogued as COSV63892583; called by muse, mutect2, varscan2
- ERVW-1 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV71259434; called by muse, mutect2, varscan2
- EXO1 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV62218736; called by mutect2, varscan2
- F13A1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.166); catalogued as rs267601095, COSV53562294; called by muse, mutect2, varscan2
- FAM83C | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs867400652, COSV65583697; called by mutect2, varscan2
- FAT3 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 196/356 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs867563989, COSV53111512; called by muse, mutect2, varscan2
- FBLN7 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55616678; called by muse, mutect2, varscan2
- FBXW9 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV100790305, COSV63509323; called by muse, mutect2, varscan2
- FECH | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV50491579; called by muse, mutect2, varscan2
- FGD4 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56782439, COSV56786675; called by muse, mutect2, varscan2
- FGF2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52651366; called by muse, varscan2
- FLG2 | c.6755G>A p.G2252E | Missense Mutation (SNP) | VAF 93/305 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.791); catalogued as COSV66170597; called by muse, mutect2, varscan2
- FREM2 | c.2923G>A p.E975K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV54842566; called by muse, mutect2, varscan2
- FRMPD1 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100899657; called by muse, mutect2, varscan2
- FRS2 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV54727770; called by muse, mutect2, varscan2
- FSCN3 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as rs759702159, COSV50001510; called by muse, mutect2, varscan2
- GABRB2 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV50925747; called by muse, mutect2, varscan2
- GAPVD1 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52925123; called by muse, mutect2, varscan2
- GET3 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV50371121; called by muse, mutect2, varscan2
- GJA10 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65355617; called by muse, mutect2, varscan2
- GLOD4 | c.245T>C p.F82S (on ENST00000301328 / NM_001366247.1; = p.F67S on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56754366; called by muse, mutect2, varscan2
- GORAB | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.34); catalogued as rs757240482, COSV63027694; called by mutect2, varscan2
- GPAT3 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1050360874, COSV52358306; called by muse, varscan2
- GPR152 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56887353; called by mutect2, varscan2
- GRXCR2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.298); catalogued as COSV65061527; called by muse, varscan2
- GSX2 | c.26C>A p.S9* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV58843244; called by muse, mutect2, varscan2
- GUCY1A1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV56653573; called by muse, mutect2, varscan2
- H4C6 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.553); catalogued as COSV66685705; called by muse, mutect2, varscan2
- HAPLN2 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV54816190; called by muse, mutect2
- HDLBP | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60499134; called by muse, mutect2, varscan2
- HGF | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as COSV55946401; called by muse, mutect2, varscan2
- HPGDS | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54774939; called by muse, mutect2, varscan2
- HS3ST1 | c.620T>A p.F207Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50024457; called by mutect2, varscan2
- HTR2C | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 79/109 reads (72%) | SIFT tolerated (0.76); PolyPhen benign (0.1); catalogued as COSV52210914; called by muse, mutect2, varscan2
- HVCN1 | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99657501; called by muse, mutect2, varscan2
- IGHA2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as rs781805725; called by muse, mutect2, varscan2
- IGKV1-16 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs562138219; called by mutect2, varscan2
- IL1B | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV54522294; called by muse, mutect2, varscan2
- IL4R | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as COSV50155412; called by muse, mutect2, varscan2
- INSRR | c.2216G>A p.R739K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV63875317; called by muse, mutect2, varscan2
- IQGAP2 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.299); catalogued as rs1365450795, COSV57177765; called by muse, mutect2, varscan2
- IRAG1 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV101351043, COSV70212096; called by muse, mutect2, varscan2
- IRF6 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.201); catalogued as COSV65419785; called by muse, mutect2, varscan2
- ITGAM | c.2605C>T p.H869Y (on ENST00000648685 / NM_001145808.2; = p.H868Y on NM_000632.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs1416007898, COSV54939479; called by muse, mutect2, varscan2
- JCAD | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV64759620; called by muse, mutect2, varscan2
- KCNC1 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.534); catalogued as COSV56396129; called by muse, mutect2, varscan2
- KCNH5 | c.2563A>T p.K855* | Nonsense Mutation (SNP) | VAF 28/51 reads (55%) | catalogued as COSV59767163; called by muse, mutect2, varscan2
- KCNK9 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.174); catalogued as COSV57280392; called by mutect2, varscan2
- KLHDC7A | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs780616009, COSV68769217; called by mutect2, varscan2
- KLHL1 | c.1798G>A p.G600S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.206); catalogued as rs746861654, COSV64776272; called by muse, mutect2, varscan2
- KPRP | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV64222241; called by muse, mutect2, varscan2
- KRT12 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52431613; called by muse, mutect2, varscan2
- KRT40 | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV66696600; called by muse, mutect2, varscan2
- KRT73 | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as rs757577717, COSV59837880; called by muse, mutect2, varscan2
- LARP1 | c.2617C>T p.Q873* (on ENST00000518297 / NM_033551.3; = p.Q796* on NM_015315.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/117 reads (22%) | catalogued as COSV60429012; called by muse, varscan2
- LARP1B | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV52799895; called by muse, mutect2, varscan2
- LCA5L | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs750728282, COSV55746319; called by mutect2, varscan2
- LCOR | c.4511C>T p.S1504F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53716037, COSV53716887; called by mutect2, varscan2
- LCTL | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV57181510, COSV57182240; called by muse, mutect2, varscan2
- LGR5 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 90/159 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57007282; called by muse, mutect2, varscan2
- LRFN2 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57825120; called by muse, mutect2, varscan2
- LRRIQ3 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as rs866672669, COSV63041491; called by mutect2, varscan2
- LSR | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1349945607, COSV61555558; called by muse, mutect2, varscan2
- LTBP1 | c.4404G>A p.M1468I (on ENST00000404816 / NM_206943.4; = p.M1142I on NM_000627.4) | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55382087; called by muse, mutect2, varscan2
- MAGEL2 | c.3694G>A p.E1232K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as rs751825273, COSV58568073; called by mutect2, varscan2
- MAP3K11 | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV58420753; called by muse, mutect2, varscan2
- MAP4 | c.1542G>A p.M514I | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV64242474; called by muse, mutect2, varscan2
- MAPK1IP1L | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.638); catalogued as COSV67106581; called by muse, varscan2
- MAPT | c.2467G>A p.E823K (on ENST00000262410 / NM_001377265.1; = p.E431K on NM_005910.5) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs769851761, COSV52244378; called by mutect2, varscan2
- MC5R | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61253958, COSV61255104; called by muse, mutect2, varscan2
- MCF2L2 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61057382; called by muse, mutect2, varscan2
- MCTP2 | c.2470G>A p.G824S | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760814481, COSV63295195; called by muse, mutect2, varscan2
- MDN1 | c.12226C>T p.P4076S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65525021; called by muse, mutect2, varscan2
- MECR | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV55286303, COSV55286934; called by muse, mutect2, varscan2
- MEX3C | c.1043C>T p.T348I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101346346; called by muse, mutect2, varscan2
- MEX3C | c.1042A>T p.T348S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101346347; called by muse, mutect2, varscan2
- MGAT4C | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59834924; called by muse, mutect2, varscan2
- MIOS | c.2575A>G p.M859V | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV60769587; called by muse, mutect2, varscan2
- MMP24 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.076); catalogued as COSV55771568; called by mutect2, varscan2
- MR1 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs775161220, COSV51580069; called by muse, mutect2, varscan2
- MRAP2 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57633292; called by muse, mutect2, varscan2
- MRC1 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs533597456, COSV53470430; called by muse, mutect2, varscan2
- MROH2B | c.2167C>T p.Q723* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as COSV68186705, COSV68187077; called by mutect2, varscan2
- MRPS35 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV50011788, COSV50012472; called by muse, mutect2, varscan2
- MSI2 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99403629; called by muse, mutect2, varscan2
- MSI2 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99403631; called by mutect2, varscan2
- MYBL2 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs1341105790, COSV53831782; called by mutect2, varscan2
- MYH15 | c.3282-1G>A p.X1094_splice | Splice Site (SNP) | VAF 21/44 reads (48%) | catalogued as CS1513511, COSV56314616; called by muse, mutect2, varscan2
- MYLK | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs971096950, COSV60615171; called by mutect2, varscan2
- MYO1E | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs930560769, COSV55690929; called by muse, mutect2, varscan2
- MYO5B | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV53224279; called by mutect2, varscan2
- MYOCD | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); catalogued as COSV58505927; called by muse, mutect2, varscan2
- NDC80 | c.1016-1G>A p.X339_splice | Splice Site (SNP) | VAF 18/69 reads (26%) | catalogued as COSV55249021; called by muse, varscan2
- NEB | c.13149G>A p.M4383I | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.067); catalogued as COSV51082817; called by mutect2, varscan2
- NEB | c.12313G>A p.E4105K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs748311158, COSV51136305; ClinVar: uncertain significance; called by mutect2, varscan2
- NFASC | c.2539C>T p.H847Y (on ENST00000339876 / NM_001378329.1; = p.H950Y on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV58371970; called by mutect2, varscan2
- NIBAN2 | c.869T>G p.V290G | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV64824885; called by muse, mutect2, varscan2
- NLRP13 | c.2525G>C p.R842P | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.397); catalogued as rs571828268, COSV100738074, COSV61622951, COSV61623773; called by muse, mutect2, varscan2
- NLRP2 | c.1615C>T p.L539F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.098); catalogued as COSV54757442; called by muse, mutect2, varscan2
- NLRP8 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV52584772; called by muse, varscan2
- NNMT | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55474457; called by muse, mutect2, varscan2
- NOTCH2 | c.4561G>A p.G1521R | Missense Mutation (SNP) | VAF 97/254 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56697392, COSV56697740; called by muse, mutect2, varscan2
- NPNT | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.135); catalogued as rs1039044017, COSV59751959; called by mutect2, varscan2
- NR1H4 | c.1040C>T p.A347V (on ENST00000551379 / NM_001206993.2; = p.A333V on NM_005123.4) | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51854144; called by muse, mutect2, varscan2
- NR3C2 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV60995216; called by muse, mutect2, varscan2
- NT5C2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV58417733; called by muse, mutect2, varscan2
- OR10AG1 | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV56633782; called by muse, mutect2, varscan2
- OR10J5 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.081); catalogued as COSV58386907; called by mutect2, varscan2
- OR10Q1 | c.883T>C p.Y295H | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57471223; called by muse, mutect2, varscan2
- OR11L1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV63314989; called by muse, mutect2, varscan2
- OR13A1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs756006418, COSV65572561; called by mutect2, varscan2
- OR2B6 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV55128533; called by mutect2, varscan2
- OR4A15 | c.497T>C p.F166S | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV59036511; called by muse, mutect2, varscan2
- OR8B2 | c.662T>A p.I221N | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66665120; called by muse, mutect2, varscan2
- OR8K3 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.242); catalogued as COSV57132218; called by muse, mutect2, varscan2
- OSBPL2 | c.259G>A p.E87K (on ENST00000313733 / NM_144498.4; = p.E75K on NM_014835.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58218210; called by mutect2, varscan2
- OSGIN2 | c.1085C>A p.T362N | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV52409686; called by muse, mutect2, varscan2
- OSMR | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs780239020, COSV57087976; called by muse, mutect2, varscan2
- OVCH1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV58965417; called by muse, mutect2, varscan2
- PARVG | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV63562245; called by muse, mutect2, varscan2
- PCDHA4 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as rs267600386, COSV63538765; called by mutect2, varscan2
- PCDHA6 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as COSV65350620; called by mutect2, varscan2
- PCDHB4 | c.1589T>G p.V530G | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.718); catalogued as COSV52024389; called by muse, varscan2
- PCDHGB3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.05); catalogued as COSV53972694, COSV53985169; called by muse, mutect2, varscan2
- PCLO | c.14297C>T p.P4766L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61637564; called by muse, mutect2, varscan2
- PCLO | c.6500C>T p.S2167L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs377569458; called by muse, mutect2, varscan2
- PDYN | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.09); catalogued as COSV54102575; called by muse, mutect2, varscan2
- PDZD4 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV51248517; called by muse, mutect2, varscan2
- PEG3 | c.2042A>G p.K681R | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.528); catalogued as rs1010583197, COSV55639607; called by muse, mutect2, varscan2
- PGD | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | catalogued as COSV54622221; called by muse, varscan2
- PIK3C3 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs775480477, COSV56277128; called by muse, mutect2, varscan2
- PPP6C | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65208416; called by muse, mutect2, varscan2
- PREX2 | c.4210C>T p.H1404Y | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs866534903, COSV55770593; called by mutect2, varscan2
- PREX2 | c.4544C>T p.S1515L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs149428879; called by mutect2, varscan2
- PRKAA2 | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1159611433, COSV64802103, COSV64806783; called by muse, mutect2, varscan2
- PRR16 | c.346G>A p.V116I (on ENST00000407149 / NM_001300783.2; = p.V93I on NM_016644.2) | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV65402039; called by muse, varscan2
- PSD3 | c.2159C>T p.S720F (on ENST00000440756; = p.S719F on NM_015310.4) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV54075523; called by muse, mutect2, varscan2
- PSG5 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as COSV61653421; called by muse, varscan2
- PTPRR | c.708C>A p.S236R | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV51738494; called by muse, mutect2, varscan2
- PTPRT | c.2643G>A p.M881I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61960695; called by mutect2, varscan2
- RAP1GAP2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV54582431; called by muse, mutect2, varscan2
- RAPGEF2 | c.3220C>T p.P1074S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs370917241; called by muse, mutect2
- RASAL3 | c.2938G>A p.D980N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs532031989, COSV54609755; called by muse, mutect2, varscan2
- RASGRF2 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV54133967; called by mutect2, varscan2
- RCAN2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.533); catalogued as COSV57815928; called by muse, mutect2
- RIMS1 | c.2966C>T p.S989F | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53456079; called by muse, mutect2, varscan2
- RNF216 | c.661G>A p.E221K (on ENST00000425013 / NM_207116.3; = p.E278K on NM_207111.4) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.487); catalogued as rs1562450421, COSV66291608; called by muse, mutect2, varscan2
- RNPEP | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs192133580, COSV55242887; called by muse, mutect2, varscan2
- RPA1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs750496171, COSV54607553; called by muse, varscan2
- RPS6KA1 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs765790037, COSV65177057; called by mutect2, varscan2
- RYR2 | c.14177T>C p.M4726T | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV63697948; called by muse, mutect2, varscan2
- SAMD10 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53875050; called by muse, mutect2
- SCGB2B2 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.788); catalogued as COSV64857246, COSV64857252; called by muse, mutect2, varscan2
- SCN9A | c.4455G>A p.M1485I (on ENST00000303354; = p.M1474I on NM_002977.3) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs866611357, COSV57603278; called by mutect2, varscan2
- SDK2 | c.5486G>A p.G1829D | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.588); catalogued as rs1456127006, COSV66191004; called by muse, mutect2, varscan2
- SDK2 | c.1245T>A p.D415E | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV66191012; called by muse, mutect2, varscan2
- SGCZ | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs201883145, COSV66018493; called by muse, mutect2, varscan2
- SGPL1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV64591942; called by muse, mutect2, varscan2
- SHANK2 | c.2056A>C p.I686L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV53608045, COSV99573225; called by muse, varscan2
- SIGLEC14 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV55781464; called by muse, mutect2, varscan2
- SLC10A7 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53887111; called by muse, mutect2, varscan2
- SLC26A5 | c.2210C>G p.A737G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.098); catalogued as COSV59703709; called by muse, mutect2, varscan2
- SLC26A5 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59703717; called by muse, mutect2, varscan2
- SLC27A6 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as rs1343429403, COSV52485120; called by muse, mutect2, varscan2
- SLC38A4 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV56969177; called by muse, mutect2, varscan2
- SLC6A18 | c.739A>T p.I247F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV57252806; called by muse, varscan2
- SLC8B1 | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs142949596; called by mutect2, varscan2
- SLC9C1 | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as rs1487978657, COSV59890161; called by mutect2, varscan2
- SLCO4C1 | c.966G>A p.W322* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV60517833, COSV60519832; called by muse, mutect2, varscan2
- SLCO6A1 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV65812552; called by muse, mutect2, varscan2
- SLITRK6 | c.2243C>T p.S748F | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs770490286, COSV68390852; called by muse, mutect2, varscan2
- SORCS3 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV63803612; called by mutect2, varscan2
- SOX30 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs377581367; called by mutect2, varscan2
- SOX7 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs758449807, COSV58731218; called by muse, mutect2, varscan2
- SPTA1 | c.5917C>A p.L1973M | Missense Mutation (SNP) | VAF 124/260 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV63756490; called by muse, varscan2
- SRRM2 | c.5192C>T p.S1731F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57076848; called by muse, mutect2, varscan2
- STS | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54269901; called by muse, mutect2, varscan2
- SYCP2L | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV51652625; called by muse, mutect2, varscan2
- TAAR6 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51584248; called by muse, mutect2, varscan2
- TBC1D21 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV55995523; called by muse, mutect2, varscan2
- TBCD | c.2752C>T p.R918C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422765982, COSV62803858; called by muse, mutect2, varscan2
- TDRD5 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54246361; called by muse, mutect2, varscan2
- TDRD6 | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60176910; called by muse, mutect2, varscan2
- TENM1 | c.7731G>T p.K2577N | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV64437227; called by muse, mutect2, varscan2
- TENM3 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as COSV69313560; called by muse, mutect2, varscan2
- TFEC | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV55403664; called by muse, varscan2
- TG | c.7540G>A p.D2514N | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757815753, COSV55064385; called by muse, mutect2, varscan2
- TGM5 | c.418T>A p.F140I | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55010955; called by muse, mutect2, varscan2
- TINAG | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs113922573, COSV52512207; called by muse, mutect2, varscan2
- TLR5 | c.742A>G p.N248D | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV60559770; called by muse, varscan2
- TLR9 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.048); catalogued as rs200601173, COSV62346198; called by muse, mutect2, varscan2
- TMEM132A | c.1462C>G p.L488V (on ENST00000453848 / NM_178031.3; = p.L489V on NM_017870.4) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as COSV50012675; called by muse, mutect2
- TMEM145 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as COSV56626390; called by muse, mutect2, varscan2
- TMEM165 | c.747G>C p.W249C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67262335; called by muse, mutect2, varscan2
- TMEM38B | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV65950619; called by mutect2, varscan2
- TMEM51 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as COSV65691243; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4673C>T p.S1558F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64101726; called by muse, mutect2, varscan2
- TNRC6B | c.5173C>G p.R1725G (on ENST00000454349 / NM_001162501.2; = p.R1615G on NM_015088.3) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57301258; called by muse, mutect2, varscan2
- TOM1L1 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as COSV100779525; called by muse, varscan2
- TPTE | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.087); catalogued as rs764249659; called by muse, mutect2, varscan2
- TRIM29 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1284523523, COSV59281363; called by muse, mutect2, varscan2
- TRIM31 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 51/156 reads (33%) | catalogued as rs867386342, COSV65060018; called by muse, mutect2, varscan2
- TRMT13 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs772813887, COSV61583425; called by mutect2, varscan2
- TSBP1 | c.379C>T p.Q127* (on ENST00000617061; = p.P144S on NM_006781.5) | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as rs748890821, COSV66660201; called by mutect2, varscan2
- TSPAN17 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV53781088; called by muse, mutect2, varscan2
- TTN | c.57211T>C p.S19071P (on ENST00000591111; = p.S11647P on NM_003319.4) | Missense Mutation (SNP) | VAF 46/115 reads (40%) | PolyPhen benign (0.326); catalogued as COSV60185722; called by muse, mutect2, varscan2
- UBXN10 | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV66772378; called by muse, mutect2, varscan2
- USP10 | c.1998G>A p.E666= | Splice Region (SNP) | VAF 7/18 reads (39%) | catalogued as COSV54750764; called by muse, mutect2, varscan2
- USPL1 | c.3101C>T p.P1034L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54998959; called by muse, mutect2, varscan2
- VPS13D | c.6569C>T p.S2190F | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1395637452, COSV50654953; called by muse, mutect2, varscan2
- VWA8 | c.5218G>A p.E1740K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64998293; called by muse, mutect2, varscan2
- WWP2 | c.1593+2T>C p.X531_splice | Splice Site (SNP) | VAF 25/97 reads (26%) | catalogued as COSV63126318; called by muse, mutect2, varscan2
- ZBBX | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56794872; called by mutect2, varscan2
- ZFPM2 | c.2786G>A p.G929E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as COSV65874707; called by muse, mutect2, varscan2
- ZNF169 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100566387; called by muse, mutect2, varscan2
- ZNF235 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52157467; called by muse, mutect2, varscan2
- ZNF556 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs770621895, COSV56911601; called by muse, mutect2, varscan2
- ZNF560 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100038281, COSV56869586; called by muse, mutect2, varscan2
- ZNF780A | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61814960; called by mutect2, varscan2
- ZNF792 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs200960200, COSV68692840; called by mutect2, varscan2
- CDKN2A | c.257_282del p.A86Gfs*25 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel
- CKAP2 | c.1602del p.S534Rfs*9 (on ENST00000378037 / NM_001098525.2; = p.S533Rfs*9 on NM_018204.5) | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- TBC1D17 | c.1467_1468del p.C490Lfs*60 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by pindel, varscan2
- XAGE2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 63/91 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ABCA4 | c.5439G>A p.L1813= | Silent (SNP) | VAF 84/184 reads (46%) | catalogued as COSV64674241, COSV64675305; called by muse, mutect2, varscan2
- ACSM1 | c.1365G>A p.K455= | Silent (SNP) | VAF 51/299 reads (17%) | catalogued as COSV54634546, COSV54637809; called by muse, mutect2, varscan2
- ACSS3 | c.570G>A p.R190= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV54095805; called by muse, mutect2, varscan2
- ADAMTS7 | c.4320C>T p.S1440= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs375540595; called by muse, varscan2
- ADAMTSL3 | c.4761C>T p.T1587= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV54457518; called by muse, mutect2, varscan2
- ADH1A | c.339G>A p.L113= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV52925544; called by mutect2, varscan2
- ADIPOR1 | c.327T>C p.Y109= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV61851993; called by muse, mutect2, varscan2
- AIFM2 | c.1083C>T p.V361= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV57159903; called by muse, mutect2, varscan2
- AL645922.1 | c.2286G>A p.K762= | Silent (SNP) | VAF 66/172 reads (38%) | catalogued as COSV54961745; called by muse, mutect2, varscan2
- AMPH | c.996C>T p.I332= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as rs755581983, COSV57749117; called by muse, mutect2, varscan2
- AOX1 | c.2838C>T p.S946= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs765053434, COSV65982771; called by muse, mutect2, varscan2
- ATP6V1B1 | c.549C>T p.I183= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV52268896; called by muse, mutect2, varscan2
- ATP7B | c.1686C>T p.S562= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs138962570, COSV54441345; ClinVar: likely benign; called by muse, mutect2, varscan2
- B3GALNT1 | c.396C>T p.S132= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs778210669, COSV57580811; called by muse, mutect2, varscan2
- BLNK | c.240C>T p.D80= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV56412478; called by muse, varscan2
- BPIFA2 | c.351C>T p.I117= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs149183452; called by mutect2, varscan2
- BRIP1 | c.1746G>A p.Q582= | Silent (SNP) | VAF 62/168 reads (37%) | catalogued as COSV52001371, COSV52003380; called by muse, mutect2, varscan2
- BTN3A1 | c.1341C>T p.P447= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as rs1397633708, COSV50025350, COSV99176338; called by mutect2, varscan2
- C6 | c.1524G>A p.R508= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs562300050, COSV54706817, COSV54709914; called by muse, mutect2, varscan2
- C8orf34 | c.1314C>T p.I438= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV57403248; called by muse, mutect2
- CATSPER2 | c.573C>T p.P191= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs764855760, COSV100390727, COSV58661383; called by muse, mutect2, varscan2
- CCDC77 | c.741C>T p.I247= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs765256443, COSV53471973; called by mutect2, varscan2
- CD1A | c.216G>A p.R72= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as COSV56863024; called by muse, mutect2, varscan2
- CDK5RAP1 | c.714C>T p.V238= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV59427861; called by mutect2, varscan2
- CHD1 | c.2088C>T p.R696= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV52342472; called by muse, mutect2, varscan2
- CHRNA9 | c.591C>T p.F197= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV59573727, COSV59574029; called by mutect2, varscan2
- CLCN1 | c.1611C>T p.S537= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV58372024; called by muse, mutect2, varscan2
- CPED1 | c.1254C>T p.S418= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs1282495810, COSV60007059; called by muse, varscan2
- CPED1 | c.2652C>T p.I884= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1182941153, COSV60007071; called by muse, mutect2
- CREBZF | c.304C>T p.L102= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV52630155; called by muse, mutect2, varscan2
- CTC1 | c.3117C>T p.L1039= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs749339785, COSV59854169; called by muse, mutect2, varscan2
- CYP4A11 | c.840G>A p.L280= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV60224427; called by muse, mutect2, varscan2
- DNAJC16 | c.1653C>T p.F551= | Silent (SNP) | VAF 175/457 reads (38%) | catalogued as rs555387198, COSV65449140; called by muse, mutect2, varscan2
- DPYD | c.2586G>A p.G862= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs903875506, COSV64608134; called by muse, mutect2, varscan2
- DPYSL2 | c.1230C>T p.V410= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV60784404; called by mutect2, varscan2
- DSCAML1 | c.3486C>T p.I1162= (on ENST00000321322; = p.I1102= on NM_020693.4) | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs267602710, COSV58396539; called by mutect2, varscan2
- DUSP13 | c.81C>T p.L27= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV57815303; called by muse, mutect2, varscan2
- DUSP8 | c.1008C>T p.T336= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs1302862250, COSV59030847; called by muse, mutect2, varscan2
- EBF2 | c.1641G>A p.R547= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV68779067, COSV99065203; called by muse, mutect2, varscan2
- EDIL3 | c.708G>A p.R236= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV56895989; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.531C>T p.L177= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV63042077; called by muse, mutect2, varscan2
- EPHA8 | c.1782C>T p.F594= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs750902137, COSV51272084; called by muse, mutect2, varscan2
- EPPK1 | c.4065C>T p.L1355= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV73261894; called by muse, mutect2, varscan2
- ESYT3 | c.444C>T p.I148= | Silent (SNP) | VAF 89/179 reads (50%) | catalogued as rs1265167433, COSV56679868; called by muse, mutect2, varscan2
- F8 | c.2289G>A p.Q763= | Silent (SNP) | VAF 61/93 reads (66%) | catalogued as COSV64276002; called by muse, mutect2, varscan2
- FAM117A | c.1257G>A p.R419= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV53603655; called by mutect2, varscan2
- FFAR4 | c.822G>A p.Q274= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV65160478; called by muse, mutect2, varscan2
- FILIP1 | c.1824A>G p.R608= | Silent (SNP) | VAF 79/206 reads (38%) | catalogued as COSV52735181; called by muse, varscan2
- FRMPD1 | c.438G>A p.E146= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs1322917978, COSV66701269; called by muse, varscan2
- FRMPD1 | c.2241C>T p.P747= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1440264455, COSV100899658; called by mutect2, varscan2
- GABRB1 | c.1050G>A p.E350= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV54990946; called by muse, mutect2, varscan2
- GADL1 | c.1038G>A p.V346= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV56982007; called by mutect2, varscan2
- GPR31 | c.867C>T p.F289= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV64761357; called by mutect2, varscan2
- GRIN2B | c.4164C>T p.I1388= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as COSV74206781; called by muse, mutect2, varscan2
- GRM3 | c.885C>T p.F295= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV64472132; called by mutect2, varscan2
- GRM6 | c.1008C>T p.I336= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs138201914; called by mutect2, varscan2
- HERC2 | c.9777C>T p.I3259= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs769159696, COSV55321972; called by mutect2, varscan2
- HVCN1 | c.690G>A p.R230= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99657500; called by muse, mutect2, varscan2
- IFI27L1 | c.258C>T p.I86= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as rs565812135, COSV67628542; called by muse, mutect2, varscan2
- IGFBP2 | c.774C>T p.I258= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV52080765; called by muse, mutect2, varscan2
- ITLN1 | c.435G>A p.K145= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV58275972, COSV58276299; called by muse, mutect2, varscan2
- KCNB2 | c.2562C>T p.S854= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV73051437; called by muse, mutect2, varscan2
- KCND3 | c.543G>A p.L181= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV56184583; called by muse, mutect2, varscan2
- KCNK2 | c.114C>T p.S38= (on ENST00000444842 / NM_001017425.3; = p.S23= on NM_014217.4) | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV67206101; called by muse, mutect2, varscan2
- KCNK6 | c.687C>T p.P229= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV54580051; called by muse, mutect2, varscan2
- KCNT2 | c.1584G>A p.R528= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs370930727, COSV99656662; called by muse, mutect2, varscan2
- KL | c.2535G>A p.V845= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV66309349; called by muse, mutect2, varscan2
- KREMEN1 | c.882C>T p.V294= (on ENST00000407188; = p.V296= on NM_032045.5) | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV59913710; called by muse, mutect2, varscan2
- KRT38 | c.396G>A p.L132= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV55846328, COSV55846753; called by muse, varscan2
- L1TD1 | c.1107G>A p.E369= | Silent (SNP) | VAF 66/151 reads (44%) | catalogued as COSV63133712; called by muse, mutect2, varscan2
- LCT | c.2199G>A p.R733= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs368409867; called by muse, mutect2, varscan2
- LEPR | c.825G>A p.E275= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV60759056; called by muse, mutect2, varscan2
- LRRC4B | c.1851C>T p.I617= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV65350349; called by mutect2, varscan2
- LRRTM3 | c.442C>T p.L148= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV63668433, COSV63673575; called by muse, mutect2, varscan2
- LSS | c.1449C>T p.L483= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV62701750; called by muse, varscan2
- MAGEA12 | c.120C>T p.S40= | Silent (SNP) | VAF 22/29 reads (76%) | catalogued as COSV63295056; called by muse, mutect2, varscan2
- MAP7D2 | c.732C>T p.A244= | Silent (SNP) | VAF 48/66 reads (73%) | catalogued as COSV65528727; called by muse, mutect2, varscan2
- MFHAS1 | c.3096C>T p.P1032= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs1421483960, COSV52284626; called by muse, mutect2, varscan2
- MIA3 | c.3357T>C p.P1119= | Silent (SNP) | VAF 40/711 reads (6%) | catalogued as COSV60515612; called by muse, mutect2
- MSLNL | c.624G>A p.L208= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99558838; called by mutect2, varscan2
- MUC16 | c.8283C>T p.F2761= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV67479008; called by mutect2, varscan2
- MYO15A | c.1305G>A p.L435= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1362969653, COSV52760605; called by muse, mutect2, varscan2
- MYO1F | c.387G>A p.K129= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs1366433201, COSV57797460; called by muse, mutect2, varscan2
- NDST4 | c.1638G>A p.L546= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV52127701; called by mutect2, varscan2
- NECTIN4 | c.708C>T p.I236= | Silent (SNP) | VAF 59/194 reads (30%) | catalogued as COSV63513335; called by muse, mutect2, varscan2
- NUP54 | c.129C>T p.A43= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV53576451; called by muse, mutect2, varscan2
- OR10T2 | c.681G>A p.L227= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV57782282; called by mutect2, varscan2
- OR11L1 | c.321C>G p.L107= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100869499; called by mutect2, varscan2
- OR1G1 | c.699G>A p.G233= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs146714964; called by muse, mutect2, varscan2
- OR4K17 | c.588G>A p.Q196= | Silent (SNP) | VAF 56/98 reads (57%) | catalogued as rs775922448, COSV59647857; called by muse, mutect2, varscan2
- OR5H1 | c.729C>T p.A243= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV63402983; called by muse, mutect2, varscan2
- OTOL1 | c.1266G>A p.Q422= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV60007643; called by muse, varscan2
- PCDHA3 | c.351C>T p.F117= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV65368882; called by muse, varscan2
- PCDHA3 | c.1014C>T p.L338= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV63543629; called by mutect2, varscan2
- PCDHA5 | c.1665G>A p.L555= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV65354379; called by muse, mutect2, varscan2
- PCDHB15 | c.396G>A p.E132= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as COSV50863391; called by muse, mutect2, varscan2
- PCDHGB1 | c.1035C>T p.F345= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV53896832, COSV53985148; called by mutect2, varscan2
- PHLDB2 | c.1134G>A p.A378= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs145708919; called by mutect2, varscan2
- PLK1 | c.1446C>T p.F482= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs1406259456, COSV55623129; called by muse, mutect2, varscan2
- PODN | c.1419C>T p.A473= (on ENST00000395871; = p.A425= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV57015202; called by muse, mutect2, varscan2
- PPEF2 | c.1689G>A p.R563= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV54424304; called by muse, mutect2, varscan2
- PTPN14 | c.1369C>T p.L457= | Silent (SNP) | VAF 83/208 reads (40%) | catalogued as COSV100872413, COSV65285687; called by muse, mutect2, varscan2
- RANBP2 | c.5775G>A p.Q1925= | Silent (SNP) | VAF 132/337 reads (39%) | catalogued as COSV51705284; called by muse, varscan2
- RBM4B | c.606C>T p.T202= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as COSV59497509; called by muse, mutect2, varscan2
- REG1A | c.231C>T p.T77= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs1254664676, COSV52070469; called by muse, mutect2, varscan2
- RNF175 | c.360C>T p.L120= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV56842791; called by muse, mutect2, varscan2
- SEC31B | c.2295C>G p.P765= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV64845036; called by muse, mutect2, varscan2
- SHANK1 | c.762C>T p.A254= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs748094229, COSV53249850; called by muse, mutect2, varscan2
- SLC15A1 | c.1422G>A p.K474= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as COSV64732523; called by muse, varscan2
- SLC24A3 | c.1548C>T p.F516= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV60114784; called by muse, mutect2, varscan2
- SLC2A12 | c.1710G>A p.V570= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV51601251; called by muse, mutect2, varscan2
- SLC6A2 | c.1794C>T p.H598= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV54920275; called by muse, mutect2, varscan2
- SOX18 | c.231C>T p.R77= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs762331997, COSV61110808; called by mutect2, varscan2
- SOX30 | c.1551C>T p.S517= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99398819; called by mutect2, varscan2
- SPTA1 | c.5916T>C p.T1972= | Silent (SNP) | VAF 124/262 reads (47%) | catalogued as COSV63756492; called by muse, mutect2, varscan2
- SRD5A2 | c.582C>T p.F194= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as CM995320, COSV51870965; called by muse, mutect2, varscan2
- SYT3 | c.252G>A p.R84= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV58895661; called by muse, mutect2, varscan2
- TBC1D16 | c.2017C>T p.L673= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV59988947; called by muse, mutect2, varscan2
- TDRD1 | c.309G>A p.R103= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV52593467; called by muse, mutect2, varscan2
- TOM1L1 | c.1143G>A p.R381= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100779529; called by muse, varscan2
- TSNAX | c.204A>G p.K68= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs1220482540, COSV64146664; called by muse, mutect2, varscan2
- TUBA1C | c.495C>T p.S165= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV56511270; called by muse, mutect2, varscan2
- UNC5B | c.690C>T p.I230= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs781650417, COSV58978709; called by mutect2, varscan2
- VPS13A | c.1506A>G p.R502= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV62433186; called by muse, mutect2, varscan2
- VWA3A | c.1005G>A p.R335= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100241363; called by muse, mutect2, varscan2
- XCR1 | c.192C>T p.S64= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV58570019; called by muse, mutect2
- ZBED9 | c.3561A>G p.E1187= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV71729640; called by muse, mutect2, varscan2
- ZDBF2 | c.4005C>T p.I1335= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV65624731; called by muse, mutect2, varscan2
- ZNF169 | c.858G>A p.G286= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as COSV100566388; called by muse, mutect2, varscan2
- ZNRF4 | c.621C>T p.I207= | Silent (SNP) | VAF 38/71 reads (54%) | catalogued as rs1054571001, COSV55774228; called by mutect2, varscan2
- ZPLD1 | c.180C>T p.F60= (on ENST00000466937 / NM_001329788.1; = p.F76= on NM_175056.2) | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV60354854; called by muse, mutect2, varscan2
- A1CF | c.-1A>T | 5'UTR (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99258087; called by muse, varscan2
- AL645933.1 | chr6:31463699 G>A | 5'Flank (SNP) | VAF 16/64 reads (25%) | catalogued as rs866267495; called by muse, varscan2
- CTNS | c.*2A>C | 3'UTR (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99251615; called by muse, mutect2, varscan2
- OFCC1 | n.556+3375G>A | Intron (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- OR2W5 | n.477C>A | RNA (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- OR4K1 | c.*2G>A | 3'UTR (SNP) | VAF 20/84 reads (24%) | catalogued as rs1432806444, COSV53458982; called by muse, mutect2, varscan2
- SERPINA13P | n.1006G>A | RNA (SNP) | VAF 14/22 reads (64%) | called by muse, mutect2, varscan2
- SNORD114-26 | n.23G>A | RNA (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- TTN | c.34354+580G>A | Intron (SNP) | VAF 45/111 reads (41%) | catalogued as rs747045877, COSV60288270; called by muse, mutect2, varscan2
- TTN | c.10361-5323C>T | Intron (SNP) | VAF 9/39 reads (23%) | catalogued as COSV60185746; called by muse, mutect2, varscan2
- TTN | c.10360+5462G>A | Intron (SNP) | VAF 37/98 reads (38%) | catalogued as rs1267658275, COSV59922417; called by muse, mutect2, varscan2
- ZNF33A | c.-69G>A | 5'UTR (SNP) | VAF 12/30 reads (40%) | catalogued as rs1419802519, COSV56726690; called by mutect2, varscan2
